Somatic mutation profile of tumor specimen TCGA-DK-A1A3-01A (aliquot TCGA-DK-A1A3-01A-11D-A13W-08) from TCGA case TCGA-DK-A1A3, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.9 years (22,235 days).
Specimen TCGA-DK-A1A3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52899841-bd50-4b31-97df-a4ff90771462.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A1A3-10A (Blood Derived Normal), aliquot TCGA-DK-A1A3-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da8fb8e5-1ea4-4297-8336-2e3d1df2df29

The open-access MAF lists 729 somatic variants for this specimen: 526 protein-altering or splice-affecting, 180 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 453, Silent 180, Nonsense Mutation 45, Splice Site 11, Intron 7, Frame Shift Ins 6, Frame Shift Del 6, RNA 6, 5'Flank 6, Splice Region 3, 5'UTR 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 55/321 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERCC2 | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55540131; called by muse, mutect2, varscan2
- NR3C2 | c.2429C>T p.S810L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); catalogued as rs41511344, CM001739, COSV60998533; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370769989, COSV54748170; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.97291T>C p.W32431R (on ENST00000591111; = p.W25007R on NM_003319.4) | Missense Mutation (SNP) | VAF 40/116 reads (34%) | PolyPhen probably damaging (0.999); catalogued as rs375159973, CM141097; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA6 | c.4774G>C p.E1592Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs771017491, COSV52644007, COSV52644344, COSV52644677; called by muse, mutect2, varscan2
- ABCC5 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV55595551; called by muse, mutect2, varscan2
- ABL1 | c.2621G>A p.R874K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.323); catalogued as COSV59339621; called by muse, mutect2, varscan2
- AC008397.2 | c.1928C>G p.S643* | Nonsense Mutation (SNP) | VAF 14/160 reads (9%) | catalogued as rs373558260; called by muse, mutect2
- ACOXL | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV67737034, COSV67738123; called by muse, mutect2, varscan2
- ACSBG2 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV53127578; called by muse, mutect2, varscan2
- ADAMTS12 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs201411671, COSV100711316, COSV61276392; called by muse, mutect2, varscan2
- ADCY10 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.113); catalogued as COSV63244251; called by muse, mutect2, varscan2
- ADCY7 | c.1677G>A p.T559= | Splice Region (SNP) | VAF 58/158 reads (37%) | catalogued as rs779876523, COSV54270273; called by muse, mutect2, varscan2
- ADGRG6 | c.657G>C p.K219N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV51600039; called by muse, mutect2, varscan2
- ADGRV1 | c.11911C>T p.H3971Y | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV67990647; called by muse, mutect2, varscan2
- ADSS2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100836824; called by muse, mutect2, varscan2
- AKR7L | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | catalogued as rs768578266; called by muse, mutect2, varscan2
- AL662899.2 | c.153C>G p.D51E | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.733); catalogued as COSV63264117; called by muse, mutect2, varscan2
- ANGPTL3 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.415); catalogued as COSV52019155; called by muse, mutect2, varscan2
- ANKAR | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV55617279; called by muse, mutect2, varscan2
- ANKFY1 | c.1950C>T p.V650= | Splice Region (SNP) | VAF 27/132 reads (20%) | catalogued as COSV58922042; called by muse, mutect2, varscan2
- ANKRD13C | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.11); catalogued as COSV52034500, COSV99256312; called by muse, mutect2, varscan2
- ANO6 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs190060422; called by muse, mutect2, varscan2
- AP3B1 | c.2303C>G p.S768* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99672069; called by muse, mutect2, varscan2
- AP3S2 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs1479464216, COSV60519719; called by muse, mutect2
- APBB1 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV54980059; called by muse, mutect2, varscan2
- APH1A | c.690C>G p.I230M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV52528611, COSV52530429; called by muse, mutect2, varscan2
- APH1A | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as COSV52530439; called by muse, mutect2, varscan2
- ARAF | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.083); catalogued as rs749564014, COSV99283529; called by muse, varscan2
- ARHGAP19 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57395582; called by muse, mutect2, varscan2
- ARHGAP32 | c.986A>G p.N329S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.172); catalogued as rs1213062026, COSV59854681; called by muse, mutect2, varscan2
- ARHGAP6 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.135); catalogued as COSV57292530; called by muse, mutect2, varscan2
- ARHGEF10 | c.2993G>A p.G998E (on ENST00000398564; = p.G973E on NM_014629.4) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347907126, COSV50672471; called by muse, mutect2, varscan2
- ARID1B | c.3224C>T p.S1075L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV51650041, COSV51650361, COSV51667258; called by muse, mutect2, varscan2
- ARID5A | c.1117G>C p.G373R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.094); catalogued as COSV62591718; called by muse, mutect2, varscan2
- ATG2A | c.4376C>G p.S1459C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV65968654; called by muse, mutect2, varscan2
- ATG4B | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs745809380, COSV60350155; called by muse, mutect2
- ATP2A3 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59229454; called by muse, mutect2
- ATP9A | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1235962124, COSV58764702; called by muse, mutect2, varscan2
- ATR | c.6930G>C p.K2310N | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV63385544; called by muse, mutect2, varscan2
- AXIN1 | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1288498476, COSV51985846; called by muse, mutect2, varscan2
- B9D1 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs148240978; called by muse, mutect2, varscan2
- BARX2 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV55652155; called by muse, varscan2
- BCL2L13 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58227317; called by muse, mutect2, varscan2
- BEST3 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56994702, COSV56995769; called by muse, mutect2, varscan2
- BICC1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65862647; called by muse, mutect2, varscan2
- BIRC6 | c.10795G>A p.A3599T | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV70204662; called by muse, mutect2, varscan2
- BLOC1S5 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.466); catalogued as rs375054652; called by muse, mutect2, varscan2
- BMT2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV51780410; called by muse, mutect2, varscan2
- BRWD1 | c.6878C>T p.S2293F | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.151); catalogued as COSV59001293; called by muse, mutect2, varscan2
- BTAF1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV56438664; called by muse, mutect2, varscan2
- BTK | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 116/215 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV58117740; called by muse, mutect2, varscan2
- BTN3A3 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs778094119, COSV55073290; called by muse, mutect2, varscan2
- BUD13 | c.144-2A>G p.X48_splice | Splice Site (SNP) | VAF 15/72 reads (21%) | catalogued as COSV52770279; called by muse, mutect2, varscan2
- BZW2 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV51757295; called by muse, mutect2, varscan2
- C2orf69 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as COSV60667373; called by muse, mutect2, varscan2
- C3orf38 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs775890059, COSV59627562; called by muse, mutect2, varscan2
- CADPS | c.3698A>G p.Y1233C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51899237; called by muse, mutect2, varscan2
- CAGE1 | c.1717G>C p.E573Q (on ENST00000512086; = p.E437Q on NM_205864.3) | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV57081237; called by muse, mutect2
- CAMTA1 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1553156387, COSV100347187, COSV57922965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARMIL2 | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs904822627, COSV58031142; called by muse, mutect2, varscan2
- CATSPERB | c.1119C>A p.F373L | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV56433528; called by muse, mutect2, varscan2
- CAVIN2 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58425621; called by muse, mutect2, varscan2
- CAVIN2 | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs1370658357, COSV58425627; called by muse, mutect2, varscan2
- CAVIN2 | c.854del p.G285Efs*90 | Frame Shift Del (DEL) | VAF 108/425 reads (25%) | catalogued as COSV58423225; called by pindel, varscan2
- CAVIN2 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 176/527 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58425646; called by muse, varscan2
- CCDC30 | c.994G>A p.E332K (on ENST00000340612; = p.E289K on NM_001080850.3) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59609018; called by muse, mutect2, varscan2
- CCDC70 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.106); catalogued as COSV54430916; called by muse, mutect2, varscan2
- CCDC77 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1313543324, COSV53475000; called by muse, mutect2, varscan2
- CCDC96 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.107); catalogued as COSV59509318; called by muse, mutect2
- CCR3 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV62464243; called by muse, mutect2, varscan2
- CD163L1 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs769433022, COSV100550707, COSV58023404; called by muse, mutect2, varscan2
- CD226 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs751466145, COSV54615588; called by muse, mutect2, varscan2
- CD47 | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV62528287; called by muse, mutect2, varscan2
- CD55 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CS982156, COSV58576658; called by muse, mutect2, varscan2
- CD8A | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52158769; called by muse, mutect2, varscan2
- CDAN1 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201057681; called by muse, mutect2, varscan2
- CDCP1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56107629; called by muse, mutect2, varscan2
- CDHR2 | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV56144195; called by muse, varscan2
- CEACAM5 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55754539; called by muse, mutect2, varscan2
- CERS6 | c.666_671del p.Y223_V224del | In Frame Del (DEL) | VAF 102/277 reads (37%) | catalogued as COSV59834750; called by mutect2, pindel, varscan2
- CES2 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1204446651, COSV57697686; called by muse, mutect2, varscan2
- CFAP221 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as rs570868554, COSV54661792; called by muse, mutect2, varscan2
- CFAP43 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV53380754; called by muse, mutect2, varscan2
- CHD5 | c.4913-1G>C p.X1638_splice | Splice Site (SNP) | VAF 15/83 reads (18%) | catalogued as COSV52423442; called by muse, mutect2, varscan2
- CHD6 | c.4008-1G>A p.X1336_splice | Splice Site (SNP) | VAF 42/129 reads (33%) | catalogued as COSV58561654, COSV58563027; called by muse, mutect2, varscan2
- CHD7 | c.3841C>T p.Q1281* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV101418498; called by muse, mutect2, varscan2
- CHERP | c.1817G>C p.G606A | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV52227315; called by muse, mutect2, varscan2
- CHFR | c.1522C>T p.Q508* (on ENST00000432561 / NM_001161345.1; = p.Q467* on NM_018223.2) | Nonsense Mutation (SNP) | VAF 60/249 reads (24%) | catalogued as rs1486915053, COSV57172515; called by muse, varscan2
- CHN1 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV69298264; called by muse, mutect2, varscan2
- CLDN4 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs200176069, COSV52896949, COSV99936548; called by muse, mutect2, varscan2
- CLEC9A | c.704A>C p.Y235S | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.045); catalogued as COSV59533825; called by muse, mutect2, varscan2
- CLINT1 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51628489; called by muse, mutect2, varscan2
- CLN8 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58671400; called by muse, mutect2, varscan2
- CLUH | c.3065G>A p.C1022Y (on ENST00000435359; = p.C1061Y on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70929931; called by muse, mutect2, varscan2
- COG2 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.093); catalogued as COSV64188127; called by muse, mutect2, varscan2
- COL24A1 | c.2543T>A p.I848N | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.74); catalogued as COSV65309537, COSV65312729; called by muse, mutect2
- COL27A1 | c.3256C>G p.P1086A | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV61930183; called by muse, mutect2, varscan2
- COL4A2 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.868); catalogued as rs374976511, COSV64624640; called by muse, mutect2
- COL6A3 | c.6485A>T p.Q2162L | Missense Mutation (SNP) | VAF 177/313 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55106080; called by muse, mutect2, varscan2
- CORO6 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61471869; called by muse, mutect2, varscan2
- CPZ | c.220G>A p.E74K (on ENST00000360986 / NM_001014447.3; = p.E63K on NM_003652.3) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59925430; called by muse, mutect2, varscan2
- CRAT | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1176306475, COSV58878862; called by muse, mutect2
- CREBBP | c.3454C>T p.Q1152* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as COSV52117005, COSV52131877; called by muse, mutect2, varscan2
- CROCC | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs762668725, COSV65013341; called by muse, mutect2, varscan2
- CRYBA4 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as COSV61322832, COSV99081174; called by muse, mutect2
- CSF1R | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs769742792, COSV53841868; called by muse, mutect2, varscan2
- CUL1 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.329); catalogued as COSV57391933; called by muse, mutect2, varscan2
- DARS1 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as CM150749, COSV51541545; called by muse, mutect2, varscan2
- DAXX | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs773398360, COSV56472310; called by muse, mutect2, varscan2
- DAZAP2 | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV66313245; called by muse, mutect2, varscan2
- DCC | c.3389G>C p.R1130T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV71439804, COSV71442724; called by muse, mutect2, varscan2
- DDHD2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68158667; called by muse, mutect2, varscan2
- DENND2D | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs1427997850, COSV62959940; called by muse, mutect2
- DGKI | c.3178G>T p.D1060Y | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55971839; called by muse, mutect2, varscan2
- DHX9 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.63); catalogued as COSV62361810; called by muse, mutect2, varscan2
- DIAPH2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61271506, COSV61284150; called by muse, mutect2, varscan2
- DIPK2A | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV59858279; called by muse, mutect2, varscan2
- DMBX1 | c.291T>G p.D97E | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63602531; called by muse, mutect2, varscan2
- DNAH5 | c.5697C>G p.I1899M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54244631, COSV54247801; called by muse, mutect2, varscan2
- DNAI2 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs143470009; called by muse, mutect2, varscan2
- DNMT3B | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52422424; called by muse, mutect2, varscan2
- DNTT | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs554084818, COSV64523595; called by muse, mutect2, varscan2
- DOCK1 | c.5422G>A p.V1808M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs779069875, COSV54736133; called by muse, mutect2, varscan2
- DOCK4 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV70325708; called by muse, mutect2, varscan2
- DOCK7 | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52019140; called by muse, mutect2, varscan2
- DRC3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as COSV58265904; called by muse, mutect2, varscan2
- DSP | c.4279G>A p.E1427K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV65795264; called by muse, mutect2, varscan2
- DSPP | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV56815492; called by muse, mutect2, varscan2
- DUSP16 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.423); catalogued as COSV53806120, COSV53809537; called by muse, mutect2, varscan2
- DUSP6 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54379439; called by muse, mutect2, varscan2
- E2F2 | c.565A>G p.N189D | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV62276770; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV62570458; called by muse, mutect2, varscan2
- EEF2 | c.218+1G>C p.X73_splice | Splice Site (SNP) | VAF 18/60 reads (30%) | catalogued as rs113603517, COSV58580763, COSV58581024; called by muse, mutect2, varscan2
- EFNB3 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV56834649; called by muse, mutect2, varscan2
- EGR3 | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57834376; called by muse, mutect2, varscan2
- ENPEP | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as rs768582870, COSV54456474; called by muse, mutect2, varscan2
- EPB41L1 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV52443541; called by muse, mutect2, varscan2
- EPB41L3 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as rs748240052, COSV59465535; called by muse, mutect2, varscan2
- EPHA1 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV51975802; called by muse, varscan2
- EPHA7 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV65194121; called by muse, mutect2, varscan2
- ERG | c.1259C>T p.S420L (on ENST00000398919 / NM_001243428.1; = p.S396L on NM_004449.4) | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV55728374, COSV55738400; called by muse, mutect2, varscan2
- ERI3 | c.597C>G p.F199L | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64832984, COSV64833361; called by muse, mutect2, varscan2
- ESPL1 | c.3133G>A p.D1045N | Missense Mutation (SNP) | VAF 86/332 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV57762728; called by muse, mutect2, varscan2
- EXO1 | c.2367C>G p.I789M | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV62219390; called by muse, mutect2, varscan2
- EXOC6 | c.2034G>C p.E678D | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.042); catalogued as COSV53331666; called by muse, varscan2
- F5 | c.5717-2A>G p.X1906_splice | Splice Site (SNP) | VAF 42/137 reads (31%) | catalogued as COSV63127628; called by muse, mutect2, varscan2
- FAM114A2 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61078632; called by muse, mutect2, varscan2
- FAM221A | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV61388495; called by muse, mutect2, varscan2
- FAM81B | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.073); catalogued as rs1335655817, COSV51986483; called by muse, mutect2, varscan2
- FAM83E | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as rs552900271, COSV99320117; called by muse, mutect2, varscan2
- FANCI | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.245); catalogued as COSV55533748; called by muse, mutect2, varscan2
- FBXL2 | c.153C>G p.N51K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52142494; called by muse, mutect2, varscan2
- FBXL7 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as COSV61652225; called by muse, mutect2, varscan2
- FBXO33 | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV53235682; called by muse, mutect2, varscan2
- FBXO38 | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.024); catalogued as COSV57031015; called by muse, mutect2, varscan2
- FER1L5 | c.4960G>A p.E1654K (on ENST00000623019; = p.E1627K on NM_001293083.2) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.339); catalogued as rs1188743163, COSV67606894; called by muse, mutect2, varscan2
- FGA | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV57400136; called by muse, mutect2, varscan2
- FGF8 | c.384G>A p.M128I (on ENST00000344255 / NM_033164.4; = p.M110I on NM_006119.6) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV60143603; called by muse, mutect2, varscan2
- FHL5 | c.158A>T p.K53M | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58740201; called by muse, mutect2, varscan2
- FLG | c.5983G>C p.E1995Q | Missense Mutation (SNP) | VAF 167/1449 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV100911378, COSV64247604; called by muse, mutect2, varscan2
- FLG2 | c.3037G>A p.G1013S | Missense Mutation (SNP) | VAF 171/555 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.746); catalogued as rs1394068561, COSV66172311; called by muse, mutect2, varscan2
- FLOT2 | c.1249-1G>A p.X417_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | catalogued as COSV67529442; called by muse, varscan2
- FMN2 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | catalogued as rs1426355851, COSV60421234; called by muse, mutect2, varscan2
- FNDC7 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV54757336; called by muse, mutect2, varscan2
- FOXS1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776132794, COSV54068006, COSV99640365; called by muse, mutect2, varscan2
- FRAS1 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs983019309, COSV53641689; called by muse, mutect2, varscan2
- FRAS1 | c.1832C>G p.S611* | Nonsense Mutation (SNP) | VAF 17/113 reads (15%) | catalogued as COSV53632380; called by muse, mutect2, varscan2
- FRMPD2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV59722827; called by muse, mutect2, varscan2
- FRRS1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs1377292229, COSV54924058; called by muse, mutect2, varscan2
- FUBP1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV53937396; called by muse, mutect2, varscan2
- G3BP2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); catalogued as COSV62977475; called by muse, mutect2, varscan2
- GAK | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749349677, COSV58508825; called by muse, mutect2, varscan2
- GATM | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67541065; called by muse, mutect2, varscan2
- GGCX | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs377362868; called by muse, mutect2, varscan2
- GGT6 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); catalogued as COSV54603274; called by muse, mutect2, varscan2
- GJA10 | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65354786; called by muse, mutect2, varscan2
- GLYAT | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.091); catalogued as COSV53540433; called by muse, mutect2, varscan2
- GNA15 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53587804; called by muse, mutect2, varscan2
- GNAS | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV55686116; called by muse, mutect2
- GNL3L | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV60577473; called by muse, mutect2, varscan2
- GOLGB1 | c.5263G>C p.E1755Q | Missense Mutation (SNP) | VAF 90/430 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV61470174; called by muse, mutect2, varscan2
- GOLGB1 | c.3097G>T p.E1033* | Nonsense Mutation (SNP) | VAF 53/271 reads (20%) | catalogued as COSV100511595, COSV61465606; called by muse, mutect2, varscan2
- GOLGB1 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 101/333 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61469896; called by muse, mutect2, varscan2
- GOLGB1 | c.2237G>C p.R746T | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV61470189; called by muse, mutect2, varscan2
- GPN2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as COSV64652622; called by muse, mutect2, varscan2
- GPR15 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs762768983, COSV52521299; called by muse, mutect2, varscan2
- GPS2 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 34/195 reads (17%) | catalogued as COSV59750339, COSV59752499; called by muse, mutect2, varscan2
- GPS2 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 35/118 reads (30%) | catalogued as COSV100223351; called by muse, mutect2, varscan2
- GREB1 | c.5041C>T p.H1681Y | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV52195038; called by muse, mutect2, varscan2
- GRIK4 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as COSV70806449, COSV70807162; called by muse, mutect2, varscan2
- GRIN2C | c.2156A>G p.K719R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV53117345; called by muse, mutect2, varscan2
- GSK3A | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55900702; called by muse, mutect2, varscan2
- GTF3C2 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 87/297 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.051); catalogued as COSV53128515; called by muse, mutect2, varscan2
- GXYLT2 | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.055); catalogued as COSV67475050; called by muse, mutect2, varscan2
- GXYLT2 | c.745A>T p.I249F | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV67475055; called by muse, mutect2, varscan2
- GYS1 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54405065; called by muse, mutect2, varscan2
- HAUS3 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as COSV54723922; called by muse, mutect2, varscan2
- HDAC4 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV61874597; called by muse, mutect2, varscan2
- HERC1 | c.5828C>T p.S1943L | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV71249888; called by muse, mutect2, varscan2
- HIP1R | c.1822C>G p.Q608E | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV53444454; called by muse, mutect2, varscan2
- HK1 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.303); catalogued as COSV53864941; called by muse, mutect2, varscan2
- HMCN1 | c.8287C>G p.Q2763E | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV54934885, COSV99623070; called by muse, mutect2, varscan2
- HMGB2 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV56634114; called by muse, mutect2, varscan2
- HNRNPF | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV61562122; called by muse, mutect2, varscan2
- HPR | c.144G>C p.L48F | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV57184341; called by muse, mutect2, varscan2
- HRC | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs756364611, COSV53255363; called by muse, mutect2, varscan2
- HSPA6 | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV100554372; called by mutect2, varscan2
- IDE | c.1219C>G p.Q407E | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.476); catalogued as COSV56426716; called by muse, mutect2, varscan2
- IFT80 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as rs781436346, COSV58446857; called by muse, mutect2, varscan2
- IL18RAP | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826052, COSV51828701; called by muse, mutect2, varscan2
- IL18RAP | c.1658C>A p.A553D | Missense Mutation (SNP) | VAF 82/263 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV51828763; called by muse, mutect2, varscan2
- IL3RA | c.617-1G>A p.X206_splice | Splice Site (SNP) | VAF 54/231 reads (23%) | catalogued as COSV58433191; called by muse, mutect2, varscan2
- INTS13 | c.1294G>C p.D432H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.823); catalogued as COSV53905075; called by muse, mutect2, varscan2
- ITGA11 | c.3208T>C p.C1070R | Missense Mutation (SNP) | VAF 81/111 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59881346; called by muse, mutect2, varscan2
- ITGA9 | c.1879_1892del p.A627Sfs*3 | Frame Shift Del (DEL) | VAF 25/138 reads (18%) | catalogued as COSV53251132; called by mutect2, pindel, varscan2
- ITPRIPL1 | c.228G>A p.W76* (on ENST00000439118 / NM_001008949.3; = p.W84* on NM_178495.6) | Nonsense Mutation (SNP) | VAF 34/116 reads (29%) | catalogued as rs201297775; called by muse, mutect2, varscan2
- ITPRIPL2 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs781035640; called by muse, mutect2
- ITSN1 | c.1652A>G p.Q551R | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.972); catalogued as COSV66085527; called by muse, mutect2, varscan2
- KATNAL2 | c.1375G>A p.E459K (on ENST00000356157 / NM_001353899.1; = p.E387K on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs867165094, COSV55299855; called by muse, mutect2, varscan2
- KCNC2 | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs746686202, COSV54368951; called by muse, mutect2, varscan2
- KCNH7 | c.2978G>A p.R993Q | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs779519091, COSV59786034; called by muse, mutect2, varscan2
- KDM3B | c.4693G>C p.D1565H | Missense Mutation (SNP) | VAF 68/358 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58694521; called by muse, mutect2, varscan2
- KDM5B | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV52512050; called by muse, varscan2
- KEAP1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV50265550, COSV50644960; called by muse, mutect2, varscan2
- KIF3C | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as COSV53101440; called by muse, mutect2, varscan2
- KPNA1 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV60271267; called by muse, mutect2, varscan2
- KPRP | c.313T>C p.S105P | Missense Mutation (SNP) | VAF 124/415 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV64222805; called by muse, mutect2, varscan2
- LAS1L | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56707691; called by muse, mutect2, varscan2
- LAX1 | c.719A>G p.D240G | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as rs780343254, COSV65850048; called by muse, mutect2, varscan2
- LRFN2 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV57825341, COSV57833555; called by muse, mutect2, varscan2
- LRIG2 | c.2495G>A p.R832K | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV63163911; called by muse, mutect2, varscan2
- LRRC4C | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as COSV53436303; called by muse, mutect2, varscan2
- LRRN3 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV57821804, COSV57823381; called by muse, mutect2, varscan2
- MACF1 | c.5235G>C p.L1745F | Missense Mutation (SNP) | VAF 11/188 reads (6%) | catalogued as COSV57140653; called by muse, mutect2
- MACF1 | c.7650G>T p.Q2550H | Missense Mutation (SNP) | VAF 30/292 reads (10%) | catalogued as COSV57140668; called by muse, mutect2
- MACF1 | c.8721G>C p.M2907I | Missense Mutation (SNP) | VAF 20/252 reads (8%) | catalogued as COSV57140678; called by muse, mutect2
- MACROH2A1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV56897747; called by muse, mutect2
- MAPKBP1 | c.1414G>A p.D472N (on ENST00000456763 / NM_001128608.2; = p.D466N on NM_014994.3) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV52966485; called by muse, mutect2, varscan2
- MBD6 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV63076256; called by muse, mutect2, varscan2
- MBD6 | c.2012dup p.T672Yfs*45 | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | catalogued as rs750430563; called by mutect2, varscan2
- MCM2 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 137/302 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV54036935; called by muse, mutect2, varscan2
- MCM4 | c.2415G>C p.L805F | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV50631198; called by muse, mutect2, varscan2
- MED13L | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56128383; called by muse, mutect2, varscan2
- MED27 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV52605275; called by muse, mutect2, varscan2
- MEP1A | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV57922254; called by muse, mutect2, varscan2
- MERTK | c.2246A>G p.Y749C | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54934859; called by muse, mutect2, varscan2
- MFSD12 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62598424; called by muse, mutect2, varscan2
- MFSD5 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 38/123 reads (31%) | catalogued as rs199567120, COSV61565594; called by muse, varscan2
- MIER1 | c.35-1G>T p.X12_splice (on ENST00000355356 / NM_001077701.3; = p.X29_splice on NM_020948.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 28/126 reads (22%) | catalogued as COSV62531941; called by muse, mutect2, varscan2
- MIER1 | c.35G>T p.G12V (on ENST00000355356 / NM_001077701.3; = p.G29V on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV62531955; called by muse, mutect2, varscan2
- MKI67 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs1165666333, COSV64076467; called by muse, mutect2, varscan2
- MMP16 | c.631T>C p.F211L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54185555; called by muse, mutect2, varscan2
- MORC3 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV68689144; called by muse, mutect2, varscan2
- MOV10 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV54146473, COSV54146965; called by muse, varscan2
- MS4A1 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100619388, COSV61942914; called by muse, mutect2, varscan2
- MSL2 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 108/334 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59444583; called by muse, mutect2, varscan2
- MTF2 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as COSV64772045; called by muse, mutect2, varscan2
- MTX3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.44); catalogued as rs1427878658, COSV72512204; called by muse, mutect2, varscan2
- MUC16 | c.15715G>A p.D5239N | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.041); catalogued as COSV67466967; called by muse, mutect2, varscan2
- MVB12B | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 30/186 reads (16%) | catalogued as COSV63257830; called by muse, mutect2, varscan2
- MXRA5 | c.4376C>T p.T1459I | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs767663953, COSV54247840; called by muse, mutect2, varscan2
- MYO10 | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV72454685; called by muse, mutect2, varscan2
- MYO1C | c.2816A>G p.Q939R (on ENST00000648651 / NM_001080779.2; = p.Q904R on NM_033375.5) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.917); catalogued as rs759488300, COSV63000467; called by muse, mutect2, varscan2
- MYO5B | c.2795G>T p.R932L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV53229020; called by muse, mutect2, varscan2
- MYOT | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53516196; called by muse, mutect2, varscan2
- NAA15 | c.1079A>G p.N360S | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56722148; called by muse, mutect2, varscan2
- NAA25 | c.2571C>A p.Y857* | Nonsense Mutation (SNP) | VAF 43/153 reads (28%) | catalogued as COSV55708745; called by muse, mutect2, varscan2
- NBN | c.2134C>T p.H712Y | Missense Mutation (SNP) | VAF 124/220 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV55376380; called by muse, mutect2, varscan2
- NCAPD2 | c.1182G>C p.Q394H | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.336); catalogued as COSV59702044; called by muse, mutect2, varscan2
- NCAPD2 | c.1389G>C p.Q463H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.336); catalogued as COSV59702059; called by muse, mutect2
- NDUFA5 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV63252023, COSV63252225; called by muse, mutect2, varscan2
- NEK8 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV52048328; called by muse, mutect2, varscan2
- NEU2 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 121/211 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52093866; called by muse, mutect2, varscan2
- NFE2L1 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199935106; called by muse, mutect2, varscan2
- NFKBIE | c.1425C>A p.D475E (on ENST00000275015; = p.D336E on NM_004556.3) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV51491579; called by muse, mutect2, varscan2
- NHLRC1 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV61481688, COSV61481826; called by muse, mutect2, varscan2
- NMD3 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63619527; called by muse, mutect2
- NSD2 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.543); catalogued as rs750333708, COSV56395592; called by muse, mutect2, varscan2
- NSUN7 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1326998128, COSV57276001; called by muse, mutect2, varscan2
- NUP107 | c.2056G>T p.A686S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs1344755266, COSV57497587; called by muse, mutect2, varscan2
- OBSCN | c.3982T>A p.Y1328N | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757106903, COSV52820568; called by muse, mutect2, varscan2
- OGG1 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV57354976; called by muse, mutect2, varscan2
- OR2C1 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59241160; called by muse, mutect2, varscan2
- OR2G2 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 135/356 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60742129; called by muse, mutect2, varscan2
- OR4A47 | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101487063, COSV71444879, COSV71445121; called by muse, mutect2
- OR5K3 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV67350601; called by muse, mutect2, varscan2
- OR6N2 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59412883; called by muse, mutect2, varscan2
- OR6Q1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 116/444 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1208591323, COSV56934432; called by muse, mutect2, varscan2
- P2RY13 | c.651C>G p.F217L | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56394168; called by muse, mutect2
- PAK3 | c.512C>T p.S171L (on ENST00000262836 / NM_001324328.2; = p.S156L on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs139949467, COSV53279664; called by muse, mutect2, varscan2
- PAPOLA | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV53484809; called by muse, mutect2, varscan2
- PCDHB10 | c.1143G>A p.M381I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1334917062, COSV53383055; called by muse, mutect2, varscan2
- PCDHGC5 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as COSV52765797; called by muse, mutect2, varscan2
- PCNT | c.8473G>C p.E2825Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as COSV64032461; called by muse, mutect2, varscan2
- PCNX4 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58307521; called by muse, mutect2, varscan2
- PDE7B | c.1011G>C p.W337C | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57506371; called by muse, mutect2, varscan2
- PDZD7 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV64647357; called by muse, mutect2, varscan2
- PELI1 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 75/262 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.061); catalogued as rs777705740, COSV62730786; called by muse, mutect2, varscan2
- PGAP1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 193/354 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV61329089; called by muse, mutect2, varscan2
- PIWIL4 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54411972; called by muse, mutect2, varscan2
- PLAAT5 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV57138244; called by muse, mutect2, varscan2
- PLCB1 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs747990888; called by muse, mutect2, varscan2
- PLPPR5 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 38/161 reads (24%) | catalogued as rs1183437568, COSV104371647; called by muse, mutect2, varscan2
- PML | c.2269C>T p.L757F | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.537); catalogued as COSV51453198; called by muse, mutect2, varscan2
- PMS2 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs1394213772, COSV56223709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POGK | c.931C>G p.R311G | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as COSV63312303; called by muse, mutect2, varscan2
- POLQ | c.4420G>A p.E1474K | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as COSV51759985; called by muse, mutect2, varscan2
- POTEF | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100665408; called by muse, mutect2, varscan2
- PPIL4 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV53568520; called by muse, mutect2, varscan2
- PPM1G | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.685); catalogued as COSV59771485; called by muse, mutect2, varscan2
- PPP1R13L | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV62909550; called by muse, mutect2, varscan2
- PPP1R15A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV52340170; called by muse, mutect2, varscan2
- PPP3CA | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV59930111; called by muse, mutect2, varscan2
- PPRC1 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs1270199757, COSV53388071; called by muse, mutect2, varscan2
- PRDM16 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as CM136479, COSV54586946; called by muse, mutect2, varscan2
- PRDM9 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57012139; called by muse, varscan2
- PRF1 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV64615775; called by muse, mutect2, varscan2
- PRPF8 | c.3577G>A p.E1193K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs1221014181, COSV59267155; called by muse, varscan2
- PRRG4 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57673401, COSV57673867; called by muse, mutect2, varscan2
- PRSS54 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV54686644; called by muse, mutect2, varscan2
- PSD3 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.036); catalogued as COSV58977617; called by muse, mutect2, varscan2
- PSD4 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.431); catalogued as COSV55529698; called by muse, mutect2, varscan2
- PSPC1 | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV58890399; called by muse, mutect2, varscan2
- PTPN21 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60851498; called by muse, mutect2, varscan2
- PTPN4 | c.1810A>T p.N604Y | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV55307942; called by muse, mutect2, varscan2
- PTPRZ1 | c.6858G>T p.R2286S | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV66444360; called by muse, mutect2, varscan2
- PWWP2B | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs891852118, COSV59453311; called by muse, mutect2, varscan2
- R3HDM1 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51531875; called by muse, mutect2, varscan2
- RAD50 | c.446_459del p.A149Gfs*10 | Frame Shift Del (DEL) | VAF 18/96 reads (19%) | catalogued as COSV54756825; called by mutect2, pindel, varscan2
- RAD51AP2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67589041; called by muse, mutect2, varscan2
- RAD51C | c.989C>A p.P330H | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61677113; called by muse, mutect2, varscan2
- RALGPS1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 70/126 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.056); catalogued as rs201112886, COSV52217859; called by muse, mutect2, varscan2
- RALY | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV55783626; called by muse, mutect2, varscan2
- RALY | c.556G>A p.E186K (on ENST00000246194 / NM_016732.3; = p.E170K on NM_007367.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV55783634; called by muse, mutect2, varscan2
- RANBP2 | c.8764G>A p.E2922K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51707376; called by muse, mutect2, varscan2
- RANBP3L | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56957505; called by muse, mutect2, varscan2
- RAP1B | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV51670339; called by muse, mutect2, varscan2
- RAPH1 | c.974G>C p.R325T (on ENST00000319170 / NM_213589.3; = p.R377T on NM_203365.4) | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57351826, COSV57357051; called by muse, mutect2, varscan2
- RASGRP3 | c.289C>A p.R97S | Missense Mutation (SNP) | VAF 68/419 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.454); catalogued as COSV67821866, COSV67824693; called by muse, mutect2, varscan2
- RASL12 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs1253582702, COSV54983124; called by muse, mutect2, varscan2
- RBM15 | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as COSV63924344; called by muse, mutect2, varscan2
- RBM4B | c.266G>A p.C89Y | Missense Mutation (SNP) | VAF 138/464 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV59498030; called by muse, mutect2, varscan2
- RDX | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1212547271, COSV58196294; called by muse, mutect2, varscan2
- REEP4 | c.182G>A p.W61* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as rs1391979648; called by muse, mutect2, varscan2
- RELA | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV58013805; called by muse, mutect2, varscan2
- REN | c.492C>G p.T164= | Splice Region (SNP) | VAF 15/60 reads (25%) | catalogued as COSV65817429, COSV65818328, COSV99689634; called by muse, mutect2, varscan2
- RFK | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV65061245; called by muse, mutect2, varscan2
- RGPD2 | c.2732C>G p.S911C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs1234111762; called by mutect2, varscan2
- RIF1 | c.1309C>T p.H437Y | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54621773; called by muse, mutect2, varscan2
- RIMS4 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV65720641; called by muse, mutect2, varscan2
- RIT1 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV64167407, COSV64167728; called by muse, mutect2, varscan2
- RITA1 | c.670C>G p.Q224E | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as COSV55323465; called by muse, mutect2, varscan2
- RNF111 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV62089225; called by muse, mutect2, varscan2
- RNF186 | c.235T>A p.S79T | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV64296940; called by muse, mutect2, varscan2
- RNF25 | c.1064C>G p.P355R | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.103); catalogued as rs146227317; called by muse, mutect2, varscan2
- RPGRIP1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV52856105; called by muse, varscan2
- RPGRIP1 | c.1029G>C p.L343F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs913020687, COSV52856119; called by muse, varscan2
- RPS18 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.431); catalogued as rs775825109, COSV65852076; called by muse, mutect2
- RPS6KC1 | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV65302328; called by muse, mutect2, varscan2
- RPS9 | c.29G>C p.R10P | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV57190820; called by muse, mutect2, varscan2
- RRAD | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55339246; called by muse, mutect2, varscan2
- RTTN | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV55350969; called by muse, mutect2, varscan2
- SACS | c.13296C>G p.F4432L | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); catalogued as COSV101207399, COSV66545952; called by muse, varscan2
- SACS | c.13148C>G p.S4383* | Nonsense Mutation (SNP) | VAF 46/184 reads (25%) | catalogued as COSV66533210; called by muse, varscan2
- SACS | c.12842C>G p.S4281C | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as rs761098842, COSV66545960; called by muse, mutect2, varscan2
- SAMD14 | c.880G>A p.G294R (on ENST00000330175 / NM_001257359.2; = p.G322R on NM_174920.4) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV50304725; called by muse, mutect2, varscan2
- SAMD15 | c.1758G>T p.Q586H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV53627808; called by muse, mutect2, varscan2
- SAP130 | c.1521C>G p.I507M | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as COSV52101860; called by muse, mutect2, varscan2
- SBF2 | c.5165C>T p.S1722F | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV56309209; called by muse, mutect2, varscan2
- SCAF4 | c.2625G>C p.L875F | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV54257033; called by muse, mutect2, varscan2
- SCUBE1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.928); catalogued as rs200592539, COSV51815803; called by muse, mutect2, varscan2
- SCUBE3 | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1464548360, COSV51460031; called by muse, mutect2, varscan2
- SDC3 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767402418, COSV59579449; called by muse, mutect2, varscan2
- SEMA4A | c.330G>C p.K110N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61773850; called by muse, mutect2, varscan2
- SERINC3 | c.351C>G p.F117L | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54858234; called by muse, mutect2, varscan2
- SETD2 | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV57448930; called by muse, mutect2, varscan2
- SF3B2 | c.676C>G p.P226A | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.15); catalogued as COSV59429855; called by muse, mutect2, varscan2
- SGK2 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV58314926; called by muse, mutect2, varscan2
- SIDT1 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263384330, COSV53506318; called by muse, mutect2, varscan2
- SLC12A4 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV57934653; called by muse, mutect2, varscan2
- SLC20A1 | c.1450G>T p.V484F | Missense Mutation (SNP) | VAF 78/310 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.367); catalogued as COSV55612920; called by muse, varscan2
- SLC27A2 | c.1209A>T p.K403N | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV51061983; called by muse, mutect2, varscan2
- SLC27A5 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.739); catalogued as COSV54021697; called by muse, mutect2, varscan2
- SLC30A6 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV50874190; called by muse, mutect2, varscan2
- SLC39A12 | c.2016G>C p.L672F (on ENST00000377369 / NM_001145195.2; = p.L635F on NM_152725.3) | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV66202015, COSV66203026; called by muse, mutect2, varscan2
- SMG7 | c.2786C>T p.S929F | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); catalogued as COSV61633896; called by muse, mutect2, varscan2
- SMPD1 | c.462C>G p.S154R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs763771413, COSV54970384; called by muse, mutect2, varscan2
- SOGA3 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as COSV64105509, COSV64105986; called by muse, mutect2, varscan2
- SPATS2 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV58922724; called by muse, mutect2, varscan2
- SPTA1 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs376169797; called by muse, mutect2, varscan2
- STAB1 | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58738002, COSV58742057; called by muse, mutect2, varscan2
- SUGP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 29/123 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53233679, COSV99448717; called by muse, mutect2, varscan2
- SUGP2 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 45/325 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58256470, COSV58264340; called by muse, mutect2, varscan2
- SUN3 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV52053277; called by muse, mutect2, varscan2
- SYCP2L | c.1021T>C p.W341R | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV51656972; called by muse, mutect2, varscan2
- SYNJ2 | c.2482G>C p.D828H | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as COSV62896995, COSV62900175; called by muse, mutect2, varscan2
- SYTL1 | c.511G>A p.E171K (on ENST00000543823; = p.E159K on NM_032872.3) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV58874155; called by muse, mutect2, varscan2
- TAOK2 | c.2444G>A p.R815K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as COSV54240236; called by muse, mutect2, varscan2
- TCF20 | c.1427C>A p.S476Y | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59495434; called by muse, varscan2
- TCF20 | c.1291C>G p.H431D | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV59495446; called by muse, varscan2
- TDP1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1408349393, COSV59644562; called by muse, mutect2, varscan2
- THADA | c.5650C>T p.Q1884* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs984749651; called by muse, mutect2, varscan2
- THADA | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 51/189 reads (27%) | catalogued as COSV100369584; called by muse, mutect2, varscan2
- THAP10 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.19); catalogued as rs200034991, COSV51437118; called by muse, mutect2, varscan2
- THBS2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV64681758; called by muse, mutect2, varscan2
- TIAF1 | c.26G>C p.R9T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV62872465; called by muse, mutect2, varscan2
- TICRR | c.2975G>C p.G992A | Missense Mutation (SNP) | VAF 170/466 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV51546238, COSV51547641; called by muse, mutect2, varscan2
- TIMELESS | c.2374T>G p.L792V | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57514684; called by muse, mutect2, varscan2
- TKTL1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV54214674, COSV99474124; called by muse, mutect2, varscan2
- TMEM130 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs781824607, COSV59557727; called by muse, mutect2, varscan2
- TMEM40 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV53148339; called by muse, mutect2, varscan2
- TMPRSS12 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 102/340 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68257143; called by muse, mutect2, varscan2
- TMTC4 | c.1557G>C p.M519I (on ENST00000376234 / NM_001350577.2; = p.M538I on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV60893419; called by muse, mutect2, varscan2
- TMX1 | c.152+1G>C p.X51_splice | Splice Site (SNP) | VAF 3/19 reads (16%) | catalogued as COSV63284979; called by muse, mutect2
- TMX2 | c.711G>C p.K237N | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV53556113; called by muse, mutect2, varscan2
- TNS3 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747272053, COSV60798061; called by muse, mutect2, varscan2
- TOGARAM1 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759654991, COSV61887498; called by muse, mutect2, varscan2
- TPCN2 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373597027; called by muse, mutect2, varscan2
- TPX2 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV55922364; called by muse, mutect2, varscan2
- TRABD2A | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59105582; called by muse, mutect2, varscan2
- TRAF3IP2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV60677033; called by muse, mutect2, varscan2
- TRIM10 | c.731A>G p.E244G | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV64994208; called by muse, mutect2, varscan2
- TRIO | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV60089842; called by muse, mutect2, varscan2
- TRMT10C | c.1129C>G p.P377A | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59306693; called by muse, mutect2, varscan2
- TROAP | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.552); catalogued as COSV57745751; called by muse, mutect2, varscan2
- TRPC3 | c.973G>A p.E325K (on ENST00000379645 / NM_001366479.2; = p.E252K on NM_003305.2) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763565119, COSV53380291; called by muse, mutect2, varscan2
- TSC1 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 22/41 reads (54%) | catalogued as COSV53764144; called by muse, mutect2, varscan2
- TSNAXIP1 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.856); catalogued as COSV54651457, COSV54651849; called by muse, mutect2, varscan2
- TTC3 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61287237, COSV61295181; called by muse, mutect2, varscan2
- TTC33 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV61802404; called by muse, mutect2, varscan2
- TTC7A | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV55414767; called by muse, mutect2, varscan2
- TTN | c.51470C>T p.S17157L (on ENST00000591111; = p.S9733L on NM_003319.4) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | PolyPhen benign (0); catalogued as COSV60297742; called by muse, mutect2, varscan2
- TTN | c.12800G>C p.G4267A (on ENST00000591111; = p.G4221A on NM_003319.4) | Missense Mutation (SNP) | VAF 51/115 reads (44%) | catalogued as COSV60297782; called by muse, mutect2, varscan2
- UBR4 | c.5252T>C p.I1751T | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV64397993; called by muse, mutect2
- UGDH | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV57099676; called by muse, mutect2, varscan2
- URB2 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs759945900, COSV51029056; called by muse, mutect2, varscan2
- URB2 | c.3308C>T p.S1103L | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1483550257, COSV51029226; called by muse, mutect2, varscan2
- USF3 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747626965, COSV57076720; called by muse, mutect2, varscan2
- USP12 | c.953A>G p.Y318C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56654475; called by muse, mutect2, varscan2
- USP39 | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 94/322 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV60383301; called by muse, mutect2, varscan2
- USP9Y | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV59100478; called by muse, mutect2, varscan2
- VSNL1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54602938; called by muse, mutect2, varscan2
- VTN | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.049); catalogued as rs782123382, COSV52648119; called by muse, varscan2
- WASHC4 | c.3318G>A p.M1106I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV59891845; called by muse, mutect2, varscan2
- WDR62 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV54338910; called by muse, mutect2, varscan2
- WDR77 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs760102324, COSV52386134; called by muse, mutect2, varscan2
- XAB2 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.4); catalogued as COSV50330922; called by muse, mutect2
- XIRP2 | c.7465A>G p.R2489G (on ENST00000628543; = p.R2664G on NM_152381.6) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54684379, COSV54729654; called by muse, mutect2, varscan2
- XPO1 | c.2746C>G p.Q916E | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as COSV68947496; called by muse, mutect2, varscan2
- ZBTB37 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62933347; called by muse, mutect2, varscan2
- ZBTB48 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs751105755, COSV66554159; called by muse, mutect2, varscan2
- ZC3HC1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1352994120, COSV61300003; called by muse, mutect2, varscan2
- ZCCHC14 | c.1925C>G p.S642W (on ENST00000268616; = p.S779W on NM_015144.3) | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51887929, COSV51889862; called by muse, mutect2, varscan2
- ZCCHC14 | c.1766C>G p.S589C (on ENST00000268616; = p.S726C on NM_015144.3) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); catalogued as COSV51889868; called by muse, mutect2, varscan2
- ZFHX4 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV51486660; called by muse, mutect2, varscan2
- ZFP36L1 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV60546978; called by muse, mutect2
- ZFP37 | c.1567G>C p.G523R | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV65288480; called by muse, mutect2, varscan2
- ZFP82 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as COSV67566544; called by muse, mutect2, varscan2
- ZMYND8 | c.409G>A p.E137K (on ENST00000311275 / NM_001363741.2; = p.E157K on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/337 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53695193, COSV53695279; called by muse, mutect2, varscan2
- ZNF160 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 130/291 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); catalogued as rs756666332, COSV62000737; called by muse, mutect2, varscan2
- ZNF165 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV66102394, COSV66102896; called by muse, mutect2, varscan2
- ZNF239 | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60019532; called by muse, mutect2, varscan2
- ZNF280A | c.1340G>A p.R447K | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57482054; called by muse, mutect2, varscan2
- ZNF460 | c.902G>C p.S301T | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV64416320; called by muse, mutect2, varscan2
- ZNF513 | c.113_114del p.L38Sfs*9 | Frame Shift Del (DEL) | VAF 39/189 reads (21%) | catalogued as COSV52010052; called by mutect2, pindel, varscan2
- ZNF514 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 82/267 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); catalogued as COSV54634891; called by muse, mutect2, varscan2
- ZNF594 | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV68386090; called by muse, mutect2, varscan2
- ZNF607 | c.574C>A p.H192N | Missense Mutation (SNP) | VAF 50/742 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62206249; called by muse, mutect2
- ZNF644 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV61350005; called by muse, mutect2, varscan2
- ZNF689 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54909974; called by muse, mutect2, varscan2
- ZNF7 | c.1550G>A p.R517K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as rs1307184065, COSV57385203; called by muse, mutect2, varscan2
- ZNF713 | c.773C>T p.S258L (on ENST00000633730 / NM_001366796.2; = p.S271L on NM_182633.3) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV70057200; called by muse, mutect2, varscan2
- ZNF816 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 158/355 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54412335; called by muse, mutect2, varscan2
- ZNF829 | c.926C>G p.S309* | Nonsense Mutation (SNP) | VAF 18/261 reads (7%) | catalogued as COSV66986663; called by muse, mutect2
- ZSCAN1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as rs372224557, COSV56602391; called by muse, mutect2, varscan2
- ZSWIM5 | c.3072G>C p.M1024I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as COSV55801796; called by muse, mutect2, varscan2
- ANAPC1 | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARAP2 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 54/259 reads (21%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.3290del p.P1097Qfs*16 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by mutect2, pindel, varscan2
- ASAH2 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- BMPER | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCL15 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- CHERP | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); called by muse, varscan2
- CPSF1 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, varscan2
- CTDP1 | c.1250A>C p.Q417P | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL2 | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- DENND5B | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- DNER | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 40/68 reads (59%) | called by muse, mutect2, varscan2
- EEF1G | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- EHD4 | c.1397C>G p.S466* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- FCN3 | c.848C>G p.S283* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2
- FNDC3B | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 11/348 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.742); called by muse, mutect2
- FOXN1 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- GOLGB1 | c.4930C>T p.Q1644* | Nonsense Mutation (SNP) | VAF 143/386 reads (37%) | called by muse, mutect2, varscan2
- GPR17 | c.251dup p.I85Hfs*246 | Frame Shift Ins (INS) | VAF 29/134 reads (22%) | called by mutect2, pindel, varscan2
- GTF2E2 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- IGHE | c.1044G>C p.Q348H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IL17RC | c.1730C>T p.S577L (on ENST00000295981 / NM_153461.4; = p.S491L on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- IMPG2 | c.1535dup p.E513Rfs*8 | Frame Shift Ins (INS) | VAF 58/209 reads (28%) | called by mutect2, pindel, varscan2
- KDM6A | c.619+4_619+7del p.X207_splice | Splice Site (DEL) | VAF 58/112 reads (52%) | called by pindel, varscan2
- KEAP1 | c.1607_1608insTG p.Y537Afs*12 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- LPXN | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2
- MRC1 | c.4323G>A p.M1441I | Missense Mutation (SNP) | VAF 220/901 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MTMR12 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 58/193 reads (30%) | called by muse, mutect2, varscan2
- MUC16 | c.9742C>T p.Q3248* | Nonsense Mutation (SNP) | VAF 26/206 reads (13%) | called by muse, mutect2, varscan2
- NAA15 | c.322_367del p.K108Yfs*39 | Frame Shift Del (DEL) | VAF 16/143 reads (11%) | called by mutect2, pindel
- NUP210L | c.3925C>T p.Q1309* | Nonsense Mutation (SNP) | VAF 37/148 reads (25%) | called by muse, mutect2, varscan2
- PCDHB16 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- PRICKLE1 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- ROBO4 | c.1949-1G>A p.X650_splice | Splice Site (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- SND1 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2
- SPATS2 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 64/209 reads (31%) | called by muse, mutect2, varscan2
- TCEA3 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TDRD6 | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 22/179 reads (12%) | called by muse, mutect2, varscan2
- TGM5 | c.1130_1144del p.S377_K382delins* (on ENST00000220420 / NM_201631.4; = p.S295_K300delins* on NM_004245.4) | Nonsense Mutation (DEL) | VAF 5/53 reads (9%) | called by mutect2, pindel
- TNFRSF25 | c.93dup p.R32Qfs*3 | Frame Shift Ins (INS) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- TOGARAM1 | c.5045C>G p.S1682* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- TRGC1 | c.219C>G p.S73R | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM44 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- TSHZ2 | c.1963G>T p.E655* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- TSKU | c.624dup p.Y209Lfs*36 | Frame Shift Ins (INS) | VAF 33/153 reads (22%) | called by mutect2, pindel, varscan2
- ZNF555 | c.1188T>A p.Y396* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- ABCC12 | c.195G>A p.V65= | Silent (SNP) | VAF 12/189 reads (6%) | catalogued as COSV60917611; called by muse, mutect2
- ABHD8 | c.942C>T p.F314= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as COSV56044054; called by muse, mutect2, varscan2
- AC006059.2 | c.1326G>A p.L442= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV59609108; called by muse, mutect2, varscan2
- AC011462.1 | c.147C>T p.F49= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs1480708368, COSV60532266; called by muse, mutect2, varscan2
- ACAP1 | c.1227C>T p.A409= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2
- ACLY | c.54C>T p.F18= | Silent (SNP) | VAF 28/223 reads (13%) | catalogued as COSV61249480; called by muse, mutect2, varscan2
- ADAM19 | c.1071T>C p.S357= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV57437976; called by muse, mutect2, varscan2
- ADCY7 | c.1731G>A p.L577= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as rs1372293294, COSV54270282; called by muse, mutect2, varscan2
- ADGRG7 | c.582A>G p.R194= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as COSV56300652; called by muse, mutect2, varscan2
- ADRA2A | c.1368C>T p.L456= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV54529755; called by muse, mutect2, varscan2
- AIMP1 | c.288G>A p.V96= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV63639469; called by muse, mutect2, varscan2
- AKR1A1 | c.783C>T p.I261= | Silent (SNP) | VAF 167/294 reads (57%) | catalogued as COSV61087565; called by muse, mutect2, varscan2
- ANO8 | c.1311C>T p.L437= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV50197182; called by muse, mutect2, varscan2
- ANXA13 | c.846G>A p.G282= | Silent (SNP) | VAF 147/282 reads (52%) | catalogued as rs762896828, COSV51626227; called by muse, mutect2, varscan2
- ARHGEF11 | c.1884G>A p.E628= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV59354313; called by muse, mutect2, varscan2
- ASPM | c.7782G>A p.Q2594= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV54137224; called by muse, varscan2
- ATP2B1 | c.2121C>G p.V707= | Silent (SNP) | VAF 73/523 reads (14%) | catalogued as COSV53812120; called by muse, mutect2, varscan2
- BARX2 | c.93C>G p.L31= | Silent (SNP) | VAF 34/224 reads (15%) | catalogued as COSV55650385; called by muse, varscan2
- BCL6B | c.1200G>C p.R400= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV53429767; called by muse, mutect2, varscan2
- BRD7 | c.561C>T p.N187= | Silent (SNP) | VAF 91/222 reads (41%) | catalogued as COSV67159959; called by muse, mutect2, varscan2
- BTN1A1 | c.42C>T p.L14= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs754549047, COSV55069357; called by muse, mutect2, varscan2
- C1orf216 | c.615C>T p.I205= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as COSV52056337; called by muse, mutect2, varscan2
- CAMK2G | c.396C>T p.I132= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1291090817, COSV59479790; called by muse, mutect2, varscan2
- CATSPER3 | c.489C>T p.I163= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV50945704; called by muse, mutect2, varscan2
- CCDC142 | c.1393C>T p.L465= (on ENST00000393965 / NM_001365575.2; = p.L458= on NM_032779.4) | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as COSV51779673, COSV51780313; called by muse, mutect2, varscan2
- CCNA1 | c.381C>T p.V127= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as COSV55223651; called by muse, mutect2, varscan2
- CELSR1 | c.969G>A p.V323= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as rs1476014813, COSV53098445; called by muse, mutect2
- CHERP | c.1962G>A p.L654= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV52227306; called by muse, mutect2, varscan2
- CIT | c.1479G>A p.L493= | Silent (SNP) | VAF 65/352 reads (18%) | catalogued as COSV55880899; called by muse, mutect2, varscan2
- COL22A1 | c.3846C>T p.G1282= | Silent (SNP) | VAF 69/113 reads (61%) | catalogued as rs373967661, COSV57356542; called by muse, mutect2, varscan2
- COX5B | c.168G>A p.K56= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs1447224553, COSV51481109; called by muse, mutect2, varscan2
- CSE1L | c.1770C>T p.Y590= | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as COSV53704693; called by muse, mutect2, varscan2
- CSF1 | c.1194G>A p.P398= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs768917240, COSV60035147; called by muse, mutect2, varscan2
- CSGALNACT1 | c.717C>A p.L239= | Silent (SNP) | VAF 64/271 reads (24%) | catalogued as COSV100175001, COSV59982506; called by muse, mutect2, varscan2
- CTTNBP2 | c.3105G>A p.V1035= | Silent (SNP) | VAF 31/218 reads (14%) | catalogued as COSV50462831; called by muse, mutect2, varscan2
- CUTA | c.204C>T p.V68= (on ENST00000488034 / NM_001014840.2; = p.V45= on NM_015921.3) | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV53385960; called by muse, mutect2, varscan2
- CYB5R1 | c.120C>G p.L40= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV65917226, COSV65917239; called by muse, mutect2, varscan2
- DGKA | c.873C>T p.I291= | Silent (SNP) | VAF 42/135 reads (31%) | catalogued as COSV59388372; called by muse, mutect2, varscan2
- DHX35 | c.519C>T p.I173= | Silent (SNP) | VAF 50/190 reads (26%) | catalogued as COSV52673765; called by muse, varscan2
- DHX57 | c.3498C>T p.F1166= | Silent (SNP) | VAF 48/171 reads (28%) | catalogued as rs1186815428, COSV54890371; called by muse, mutect2, varscan2
- DLC1 | c.3864G>A p.E1288= (on ENST00000276297 / NM_001348081.2; = p.E851= on NM_006094.5) | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs1335620153, COSV52324664; called by muse, mutect2, varscan2
- DNAJC13 | c.2016G>A p.E672= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as rs768558614, COSV53456875; called by muse, mutect2, varscan2
- DNASE2B | c.282A>G p.L94= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV65743810; called by muse, mutect2, varscan2
- DOCK8 | c.4197G>A p.K1399= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV66623316; called by muse, mutect2, varscan2
- DOCK8 | c.4620C>T p.A1540= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs761144966; called by muse, mutect2
- DSP | c.4653G>A p.V1551= | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as COSV65795270; called by muse, mutect2, varscan2
- DUSP16 | c.933C>G p.L311= | Silent (SNP) | VAF 58/163 reads (36%) | catalogued as COSV53809543; called by muse, varscan2
- DUSP16 | c.855C>T p.F285= | Silent (SNP) | VAF 60/224 reads (27%) | catalogued as COSV53809551; called by muse, varscan2
- DYNC1H1 | c.13236C>T p.F4412= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV64134568, COSV64141607; called by muse, mutect2, varscan2
- EGFL8 | c.312C>T p.H104= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1301477106, COSV61248589; called by muse, mutect2, varscan2
- ELP5 | c.540C>T p.L180= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV59709217; called by muse, mutect2, varscan2
- ENTPD7 | c.633G>A p.V211= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as COSV65113152, COSV65113555; called by muse, mutect2, varscan2
- EPHA10 | c.1572C>T p.R524= | Silent (SNP) | VAF 48/142 reads (34%) | catalogued as rs777640555, COSV57626852; called by muse, mutect2, varscan2
- EPHA8 | c.2175G>C p.L725= | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as COSV51292266; called by muse, mutect2, varscan2
- ESRP1 | c.118C>T p.L40= | Silent (SNP) | VAF 50/93 reads (54%) | catalogued as COSV64409971; called by muse, mutect2, varscan2
- ESYT1 | c.2820C>T p.L940= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs758858635, COSV57275946; called by muse, mutect2, varscan2
- FBN3 | c.8050C>A p.R2684= | Silent (SNP) | VAF 43/222 reads (19%) | catalogued as rs200333959, COSV54471077; called by muse, mutect2, varscan2
- FCGBP | c.7839C>G p.A2613= | Silent (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- FCN1 | c.594C>G p.A198= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- FCN2 | c.525G>A p.L175= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV52477077; called by muse, mutect2, varscan2
- FEM1B | c.702C>T p.V234= | Silent (SNP) | VAF 36/538 reads (7%) | catalogued as rs142803256; called by muse, mutect2
- FLNB | c.3429C>T p.L1143= | Silent (SNP) | VAF 60/186 reads (32%) | catalogued as rs937646550, COSV55893305; called by muse, mutect2, varscan2
- FLVCR1 | c.342C>T p.F114= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV63134086; called by muse, mutect2, varscan2
- GABRB2 | c.702C>A p.L234= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV50938318, COSV99195873; called by muse, mutect2, varscan2
- GALM | c.60G>A p.E20= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV55373682; called by muse, mutect2, varscan2
- GARRE1 | c.987G>A p.Q329= | Silent (SNP) | VAF 46/161 reads (29%) | catalogued as COSV55103290; called by muse, mutect2, varscan2
- GATAD2A | c.1296G>A p.K432= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1233483998, COSV53075120; called by muse, mutect2, varscan2
- GIMAP8 | c.612C>T p.F204= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV56233417; called by muse, mutect2, varscan2
- GIN1 | c.306A>G p.T102= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs782282421, COSV67537660; called by muse, mutect2, varscan2
- GOLGB1 | c.2967G>A p.E989= | Silent (SNP) | VAF 63/259 reads (24%) | catalogued as COSV61470179; called by muse, mutect2, varscan2
- GORASP1 | c.1113G>A p.L371= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV56530569; called by muse, mutect2, varscan2
- GREB1 | c.4167C>T p.D1389= | Silent (SNP) | VAF 41/311 reads (13%) | catalogued as COSV52195030; called by muse, mutect2, varscan2
- GRHL3 | c.249G>A p.R83= (on ENST00000350501 / NM_198174.3; = p.R88= on NM_021180.3) | Silent (SNP) | VAF 22/260 reads (8%) | catalogued as COSV52570393; called by muse, mutect2
- H2AC16 | c.360G>A p.K120= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV104403563, COSV58901309; called by muse, mutect2, varscan2
- H4C9 | c.240G>A p.K80= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV62890200; called by muse, mutect2, varscan2
- HCN1 | c.951C>T p.F317= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV57533808; called by muse, mutect2, varscan2
- HELZ | c.2730A>G p.V910= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as COSV62380575; called by muse, mutect2
- HELZ2 | c.4728G>A p.L1576= (on ENST00000467148 / NM_001037335.2; = p.L1007= on NM_033405.3) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV71295948; called by muse, mutect2
- HOXC6 | c.522C>T p.I174= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as COSV54538035; called by muse, mutect2, varscan2
- HP | c.888G>A p.L296= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV63326381; called by muse, mutect2, varscan2
- IGFN1 | c.2076G>A p.L692= (on ENST00000295591 / NM_001367841.1; = p.L3149= on NM_001164586.2) | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV55183037; called by muse, mutect2, varscan2
- KALRN | c.3513G>A p.L1171= | Silent (SNP) | VAF 78/222 reads (35%) | catalogued as COSV53777947; called by muse, mutect2, varscan2
- KLC1 | c.249G>A p.L83= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV55808958; called by muse, mutect2, varscan2
- KLHL42 | c.714C>T p.P238= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs773820049, COSV67146208; called by muse, mutect2, varscan2
- KMT2A | c.2637G>A p.E879= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV63291627; called by muse, mutect2, varscan2
- KRT34 | c.51G>A p.Q17= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV67450571; called by muse, mutect2, varscan2
- LFNG | c.675C>T p.V225= (on ENST00000222725 / NM_001040167.2; = p.V96= on NM_002304.2) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs369216499; called by muse, mutect2, varscan2
- LPGAT1 | c.330G>A p.L110= | Silent (SNP) | VAF 125/421 reads (30%) | catalogued as COSV65352442; called by muse, mutect2, varscan2
- LRRTM1 | c.1305C>T p.L435= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV54441346, COSV54446027; called by muse, mutect2, varscan2
- LSR | c.1311C>G p.L437= (on ENST00000361790; = p.L418= on NM_015925.6) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV55888111; called by muse, mutect2, varscan2
- MAGEB10 | c.633C>T p.I211= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV63312537; called by muse, mutect2, varscan2
- MBD2 | c.657G>A p.Q219= | Silent (SNP) | VAF 77/239 reads (32%) | catalogued as COSV56503850; called by muse, mutect2, varscan2
- MDC1 | c.333G>A p.V111= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV64527027; called by muse, mutect2, varscan2
- MERTK | c.1110G>A p.V370= | Silent (SNP) | VAF 46/153 reads (30%) | catalogued as COSV54934845; called by muse, mutect2, varscan2
- MIOX | c.774C>T p.C258= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as rs1276354541, COSV53314557; called by muse, mutect2, varscan2
- MOB4 | c.30G>A p.L10= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV52095778; called by muse, mutect2
- MOV10 | c.876G>T p.G292= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV62492518; called by muse, mutect2, varscan2
- MPEG1 | c.1518C>G p.L506= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV57089661; called by muse, mutect2, varscan2
- MRPL58 | c.573G>A p.K191= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs1385759123, COSV56901798; called by muse, mutect2, varscan2
- MTG1 | c.477C>T p.L159= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV58152915, COSV58155089; called by muse, mutect2, varscan2
- MYH9 | c.5376C>T p.V1792= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV53392282; called by muse, mutect2, varscan2
- MYO1A | c.1059C>G p.L353= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV55657009; called by muse, mutect2
- MYO5B | c.2796G>T p.R932= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV53229011; called by muse, mutect2, varscan2
- MYO5C | c.1065G>A p.L355= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV55911310; called by muse, mutect2, varscan2
- MYO9B | c.768C>G p.L256= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV68282371; called by muse, mutect2, varscan2
- MYSM1 | c.1365G>A p.L455= | Silent (SNP) | VAF 53/168 reads (32%) | catalogued as COSV68978204; called by muse, mutect2, varscan2
- MYT1 | c.411C>G p.V137= | Silent (SNP) | VAF 22/155 reads (14%) | catalogued as COSV60512217; called by muse, mutect2, varscan2
- NBEAL2 | c.5652G>A p.V1884= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV52762397; called by muse, mutect2, varscan2
- NDST4 | c.1389C>T p.F463= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs759146312, COSV52112891, COSV52134539; called by muse, mutect2, varscan2
- NLRP1 | c.1194C>T p.I398= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV52576624; called by muse, mutect2, varscan2
- NMI | c.897A>G p.Q299= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as COSV54639066; called by muse, mutect2, varscan2
- NOP56 | c.603G>A p.V201= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV61391289; called by muse, mutect2, varscan2
- NPC1L1 | c.894C>T p.V298= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV56929618; called by muse, mutect2, varscan2
- NUTM2F | c.1158C>G p.V386= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV53559946, COSV99480374; called by muse, mutect2, varscan2
- OLFML3 | c.1203G>A p.K401= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV57436763; called by muse, mutect2, varscan2
- OR51Q1 | c.756C>G p.V252= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV56178450, COSV56180355; called by muse, mutect2, varscan2
- OS9 | c.1869C>T p.F623= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs945587258, COSV57731098; called by muse, mutect2
- OSBP | c.1698C>T p.F566= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as rs1338650435, COSV55665306, COSV99803299; called by muse, mutect2, varscan2
- OTOP2 | c.1557C>T p.F519= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV58883476; called by muse, mutect2, varscan2
- OXTR | c.699C>T p.L233= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs763232730; called by muse, mutect2
- PANK3 | c.489T>C p.F163= | Silent (SNP) | VAF 30/194 reads (15%) | catalogued as COSV53325020; called by muse, mutect2, varscan2
- PARPBP | c.777C>T p.F259= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as COSV59676151; called by muse, mutect2, varscan2
- PCDHB8 | c.1593G>C p.R531= | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as rs782469014, COSV50755816, COSV50774307, COSV50808561; called by muse, mutect2, varscan2
- PDZRN4 | c.2826C>T p.S942= (on ENST00000402685 / NM_001164595.2; = p.S684= on NM_013377.4) | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs777542347, COSV54214946; called by muse, mutect2, varscan2
- PFKFB2 | c.60T>C p.N20= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV60006979; called by muse, mutect2, varscan2
- PIK3R5 | c.1245C>T p.R415= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV52658037; called by muse, mutect2, varscan2
- PKHD1 | c.2793C>T p.P931= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV61891972; called by muse, mutect2, varscan2
- PKIG | c.36C>T p.I12= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV63068797; called by muse, mutect2, varscan2
- PLCD3 | c.810G>A p.L270= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV59562744; called by muse, mutect2, varscan2
- PLCD4 | c.1551C>T p.F517= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV68745333; called by muse, mutect2, varscan2
- PLEKHM3 | c.1848C>T p.F616= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV66815529; called by muse, mutect2, varscan2
- PLK3 | c.1125C>T p.L375= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV59500983; called by muse, mutect2, varscan2
- PLXNA3 | c.4404C>T p.L1468= | Silent (SNP) | VAF 40/65 reads (62%) | catalogued as rs1557208433, COSV63755414; called by muse, mutect2, varscan2
- PLXND1 | c.3828C>T p.I1276= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1420696102, COSV60718920; called by muse, mutect2, varscan2
- PPRC1 | c.2199G>A p.L733= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV53388080; called by muse, mutect2, varscan2
- PPRC1 | c.3147G>A p.Q1049= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV53388094; called by muse, mutect2, varscan2
- PRPF8 | c.3624C>A p.T1208= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV59262691, COSV59267148; called by muse, varscan2
- PTPN13 | c.4677A>G p.G1559= (on ENST00000411767 / NM_080683.3; = p.G1540= on NM_006264.3) | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as COSV57415963; called by muse, mutect2, varscan2
- PUM2 | c.3141G>A p.L1047= | Silent (SNP) | VAF 86/318 reads (27%) | catalogued as rs1287999624, COSV57584717; called by muse, mutect2, varscan2
- RAPGEF1 | c.3177G>C p.L1059= | Silent (SNP) | VAF 36/198 reads (18%) | catalogued as COSV64701917; called by muse, varscan2
- RBBP4 | c.1140C>T p.F380= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as rs1487748212, COSV65133301; called by muse, mutect2, varscan2
- RBM4 | c.490C>A p.R164= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV59518019, COSV59520072; called by muse, mutect2, varscan2
- SLC26A4 | c.1938C>G p.V646= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV55919558; called by muse, mutect2, varscan2
- SLC33A1 | c.462C>T p.F154= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as COSV63947678; called by muse, mutect2, varscan2
- SLC37A2 | c.420C>T p.I140= | Silent (SNP) | VAF 31/171 reads (18%) | catalogued as COSV53524948; called by muse, mutect2, varscan2
- SLC41A2 | c.861C>T p.F287= | Silent (SNP) | VAF 64/229 reads (28%) | catalogued as COSV51610245; called by muse, mutect2, varscan2
- SLC9A2 | c.120G>A p.P40= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV52134842; called by muse, mutect2, varscan2
- SLC9A8 | c.1527C>T p.L509= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV64290937; called by muse, mutect2, varscan2
- SNX19 | c.207C>T p.L69= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs775388355, COSV56284693, COSV99773767; called by muse, mutect2, varscan2
- SNX30 | c.636G>A p.K212= | Silent (SNP) | VAF 24/199 reads (12%) | catalogued as COSV65294030; called by muse, mutect2, varscan2
- SPAST | c.186G>C p.A62= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV59517004; called by muse, mutect2, varscan2
- SRCAP | c.4335C>T p.T1445= | Silent (SNP) | VAF 32/164 reads (20%) | catalogued as rs761618440, COSV52679710; called by muse, mutect2, varscan2
- TACC2 | c.2331G>A p.G777= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as rs769911320, COSV57748612; called by muse, mutect2, varscan2
- TAF1A | c.648C>T p.F216= | Silent (SNP) | VAF 92/266 reads (35%) | catalogued as COSV61919629; called by muse, mutect2, varscan2
- TAX1BP1 | c.261C>T p.F87= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV55290784, COSV55296324; called by muse, mutect2, varscan2
- TEX29 | c.21G>A p.V7= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs780337071, COSV52096522; called by muse, mutect2, varscan2
- TEX43 | c.177C>T p.F59= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV64036318; called by muse, mutect2, varscan2
- THBS3 | c.39C>T p.L13= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs1222197678, COSV57427912; called by muse, mutect2, varscan2
- TLE6 | c.633G>A p.R211= (on ENST00000246112 / NM_001143986.2; = p.R88= on NM_024760.3) | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV55737460; called by muse, mutect2, varscan2
- TMCC3 | c.1263C>T p.F421= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV54157235; called by muse, mutect2, varscan2
- TMEM74 | c.120C>G p.L40= | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as COSV52462492, COSV52464550; called by muse, varscan2
- TMPRSS11F | c.727C>T p.L243= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs996953103, COSV62468968; called by muse, mutect2
- TMTC1 | c.1137G>A p.E379= (on ENST00000539277 / NM_001193451.2; = p.E271= on NM_175861.3) | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs745930782, COSV55492048; called by muse, mutect2, varscan2
- TRIM29 | c.384C>G p.R128= | Silent (SNP) | VAF 45/284 reads (16%) | catalogued as COSV59281982; called by muse, mutect2, varscan2
- TTC23L | c.789G>A p.Q263= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV72205907, COSV72205981; called by muse, mutect2, varscan2
- UBE2O | c.3621C>T p.G1207= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV60067130; called by muse, mutect2
- UNC13D | c.165C>G p.L55= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV52886969; called by muse, mutect2, varscan2
- UPF1 | c.1017G>A p.K339= | Silent (SNP) | VAF 63/173 reads (36%) | catalogued as COSV53201113; called by muse, mutect2, varscan2
- URB2 | c.1494C>T p.L498= | Silent (SNP) | VAF 69/216 reads (32%) | catalogued as COSV51028745; called by muse, mutect2, varscan2
- UTS2 | c.372C>G p.V124= | Silent (SNP) | VAF 49/347 reads (14%) | catalogued as COSV50013842; called by muse, mutect2, varscan2
- XDH | c.2889C>T p.F963= | Silent (SNP) | VAF 53/264 reads (20%) | catalogued as COSV65149136; called by muse, mutect2, varscan2
- XIRP2 | c.7878C>T p.P2626= (on ENST00000628543; = p.P2801= on NM_152381.6) | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV54729666; called by muse, mutect2, varscan2
- XYLT2 | c.1875G>A p.L625= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV50016617, COSV50017226; called by muse, mutect2, varscan2
- YLPM1 | c.816G>A p.K272= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- ZBTB22 | c.1459C>T p.L487= | Silent (SNP) | VAF 39/184 reads (21%) | catalogued as rs1291584883, COSV56472286; called by muse, mutect2, varscan2
- ZBTB22 | c.264C>G p.L88= | Silent (SNP) | VAF 27/196 reads (14%) | catalogued as COSV56472291; called by muse, mutect2, varscan2
- ZC3H12A | c.807C>T p.F269= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs745695390, COSV66103818; called by muse, mutect2, varscan2
- ZNF320 | c.1497C>T p.C499= | Silent (SNP) | VAF 27/180 reads (15%) | catalogued as COSV67088815; called by muse, mutect2, varscan2
- ZNF557 | c.630C>T p.F210= (on ENST00000414706 / NM_001044388.2; = p.F217= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV53275251; called by muse, mutect2, varscan2
- ZNF700 | c.1365C>T p.F455= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as COSV54315005; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501928 G>A | 5'Flank (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503742 G>A | 5'Flank (SNP) | VAF 30/112 reads (27%) | catalogued as rs756149364; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500271 G>A | 5'Flank (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500511 G>C | 5'Flank (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500711 G>C | 5'Flank (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- CLLU1 | n.959G>A | RNA (SNP) | VAF 26/115 reads (23%) | catalogued as COSV65903452; called by muse, mutect2, varscan2
- DNAH14 | c.749-4282G>A | Intron (SNP) | VAF 33/92 reads (36%) | catalogued as COSV64782412; called by muse, mutect2, varscan2
- ETNK1 | c.-237G>A | 5'UTR (SNP) | VAF 4/13 reads (31%) | catalogued as COSV56889140; called by muse, mutect2, varscan2
- MACF1 | c.15832-11445C>T | Intron (SNP) | VAF 31/191 reads (16%) | catalogued as COSV99240459; called by muse, mutect2, varscan2
- MALAT1 | n.84G>A | RNA (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- MGAT4B | c.98-83C>T | Intron (SNP) | VAF 24/129 reads (19%) | catalogued as COSV52979360; called by muse, mutect2, varscan2
- MIR155 | n.46C>T | RNA (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- MIR548H4 | n.62C>T | RNA (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- NRP1 | c.981+4511G>A | Intron (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-649G>A | Intron (SNP) | VAF 8/21 reads (38%) | catalogued as rs1315326267; called by muse, mutect2
- PDLIM3 | c.162-1657C>T | Intron (SNP) | VAF 43/213 reads (20%) | catalogued as rs150809809; called by muse, mutect2, varscan2
- SLC3A2 | chr11:62855357 A>G | 5'Flank (SNP) | VAF 34/109 reads (31%) | called by muse, mutect2, varscan2
- SLC48A1 | c.*230G>A | 3'UTR (SNP) | VAF 31/111 reads (28%) | catalogued as COSV99317033; called by muse, mutect2
- SNORD115-42 | n.34G>C | RNA (SNP) | VAF 66/386 reads (17%) | called by muse, mutect2, varscan2
- SNORD3B-2 | n.16G>A | RNA (SNP) | VAF 11/51 reads (22%) | catalogued as rs751972602; called by muse, varscan2
- SYTL2 | c.1459+1705C>T | Intron (SNP) | VAF 50/369 reads (14%) | catalogued as rs372983553; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 10/34 reads (29%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TRIM8 | c.*414C>G | 3'UTR (SNP) | VAF 4/45 reads (9%) | catalogued as COSV56661911; called by muse, mutect2, varscan2
